Somatic mutation profile of tumor specimen PCProject_0213_T1_WES (aliquot PCProject_0213_T1_WES_1) from CMI case PCProject_0213, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.1 years (23,768 days).
Specimen PCProject_0213_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61cc80ff-6d8e-4e64-b0df-3750ddf8a752.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0213_SALIVA (Saliva), aliquot PCProject_0213_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e9c2106-30cb-4fc4-a83e-e48c38232f47

The open-access MAF lists 43 somatic variants for this specimen: 30 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 9, Splice Site 2, Intron 2, 3'Flank 2, Nonsense Mutation 1, Frame Shift Del 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>C p.G509A (on ENST00000288602 / NM_001374244.1; = p.G469A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/280 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FOXA1 | c.764_769del p.E255_N256del | In Frame Del (DEL) | VAF 12/63 reads (19%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ATOH1 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as rs1395951815; called by muse, mutect2, varscan2
- COL4A2 | c.4952G>A p.R1651H | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769994500, COSV64633022; called by muse, mutect2, varscan2
- DIS3L2 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs1342000775; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH1 | c.4940C>T p.A1647V | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1261590679; called by muse, mutect2, varscan2
- EFCAB6 | c.2750C>T p.S917L | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs762875526, COSV53067265; called by muse, mutect2, varscan2
- GKN2 | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as rs1288978530; called by muse, mutect2
- HMCN1 | c.16783C>T p.R5595* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as rs1412752744, COSV54884056, COSV99633533; called by muse, mutect2, varscan2
- MYH6 | c.3073T>A p.S1025T | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs371209775; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7B | c.1001T>G p.L334R | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs758183416; called by muse, mutect2, varscan2
- PNPLA6 | c.-42-6del | Splice Region (DEL) | VAF 23/128 reads (18%) | catalogued as COSV51173835, COSV51174385; called by mutect2, pindel, varscan2
- SOCS5 | c.219G>T p.K73N | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.018); catalogued as COSV60605117; called by muse, mutect2, varscan2
- TSC1 | c.1975G>T p.A659S | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV53765594; called by muse, mutect2, varscan2
- ZBTB7A | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.831); catalogued as rs1320096185; called by muse, mutect2, varscan2
- ADAM10 | c.1420G>A p.G474S | Missense Mutation (SNP) | VAF 103/314 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCAF11 | c.110A>G p.D37G | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- DNAAF3 | c.886C>T p.R296W (on ENST00000524407 / NM_001256715.2; = p.R343W on NM_178837.4) | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- F5 | c.985T>C p.C329R | Missense Mutation (SNP) | VAF 93/311 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GCKR | c.1018A>T p.I340F | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- GTPBP4 | c.654+1G>T p.X218_splice | Splice Site (SNP) | VAF 27/110 reads (25%) | called by muse, mutect2, varscan2
- HAPLN2 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRRN4CL | c.74C>G p.P25R | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- MBD6 | c.497del p.P166Qfs*13 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- ORC2 | c.1022G>C p.G341A | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SHH | c.760G>A p.V254M | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- TP53 | c.771_782+1del p.X257_splice | Splice Site (DEL) | VAF 15/78 reads (19%) | called by mutect2, pindel, varscan2
- UGT3A1 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- ZNF292 | c.7637A>G p.K2546R | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZNF792 | c.1253G>T p.G418V | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAJC16 | c.1380G>A p.V460= | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as rs753034625; called by muse, mutect2, varscan2
- DOCK9 | c.4218G>A p.T1406= (on ENST00000376460 / NM_001366676.2; = p.T1407= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/157 reads (32%) | catalogued as rs370435579, COSV59642139; called by muse, mutect2, varscan2
- ERBB2 | c.78C>T p.C26= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs1021403569; called by muse, mutect2
- HEPHL1 | c.3165C>T p.I1055= | Silent (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- KIAA0586 | c.3990C>A p.P1330= (on ENST00000619416 / NM_001244190.2; = p.P1269= on NM_014749.5) | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV99709027; called by muse, mutect2, varscan2
- PCDHA1 | c.2046G>A p.A682= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV65376283; called by muse, mutect2, varscan2
- RASSF10 | c.321G>A p.K107= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs759424003; called by muse, mutect2, varscan2
- SNX29 | c.42G>A p.L14= | Silent (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- TMEM59L | c.60G>A p.P20= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, varscan2
- C14orf132 | chr14:96090607 G>T | 3'Flank (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- GTF2A1 | c.338-1091G>A | Intron (SNP) | VAF 54/219 reads (25%) | called by muse, mutect2, varscan2
- KMT5B | c.377+650G>T | Intron (SNP) | VAF 35/164 reads (21%) | called by muse, mutect2, varscan2
- MIF | chr22:23895479 C>G | 3'Flank (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2
